Gene-level copy-number profile of tumor specimen ALCH-AEFA-TTP1-A from ALCHEMIST case ALCH-AEFA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.0 years (25,556 days).
Specimen ALCH-AEFA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6324ac19-94e6-4e3e-aa39-0d2055f58a42.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEFA-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/e6122183-007a-4322-93b8-8f3d67da353a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 66; copy number 1: 2,865; copy number 2: 53,349; copy number 3: 1,546; copy number 4: 572; copy number 5: 3; copy number 6: 1; copy number 11: 1; copy number 27: 1.

Homozygous deletions (total copy number 0; autosomes only): 66 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:131,491,160–131,521,573, 2 genes (within-gene range 0–2): MIR4784, SMPD4BP.
- chr4:8,558,725–8,619,761, 2 genes: GPR78, CPZ.
- chr6:26,896,952–26,898,777, 1 gene (within-gene range 0–2): POM121L6P.
- chr9:131,096,476–131,123,152, 1 gene: AIF1L.
- chr15:22,225,278–22,225,329, 1 gene: MIR1268A.
- chr15:25,170,723–25,250,940, 44 genes (within-gene range 0–2): SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:73,319,859–73,368,958, 2 genes: HCN4, AC068397.2.
- chr16:32,635,673–32,636,045, 1 gene: AC133569.1.
- chr16:58,025,754–58,046,901, 1 gene: MMP15.
- chr17:17,776,686–17,779,529, 2 genes (within-gene range 0–2): SMCR5, AC122129.2.
- chr18:79,420,836–79,422,780, 1 gene (within-gene range 0–1): AC018445.3.
- chr19:7,888,505–7,919,157, 6 genes: LRRC8E, AC010336.1, MAP2K7, AC010336.4, TGFBR3L, AC010336.2.
- chr21:43,107,942–43,168,646, 1 gene (within-gene range 0–22): AP001631.2.
- chr21:43,159,066–43,162,277, 1 gene: AP001631.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:97,737,894–97,738,913, 1 gene, copy number 5: AC112203.1.
- chr7:74,773,962–74,851,551, 2 genes, copy number 6–11: NCF1, GTF2IRD2.
- chr15:22,125,511–22,126,434, 1 gene, copy number 5 (within-gene range 2–5): OR4N3P.
- chr20:33,702,758–33,720,319, 1 gene, copy number 5: PXMP4.
- chr21:43,169,008–43,172,805, 1 gene, copy number 27: CRYAA.

Autosomal genes at a single copy (total copy number 1): 892. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
